Somatic mutation profile of tumor specimen TCGA-DD-A1EH-01A (aliquot TCGA-DD-A1EH-01A-11D-A12Z-10) from TCGA case TCGA-DD-A1EH, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 23.3 years (8,499 days).
Specimen TCGA-DD-A1EH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4071139d-dd6d-46ac-9432-f3465e4f5ab1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A1EH-10A (Blood Derived Normal), aliquot TCGA-DD-A1EH-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9a5c2307-24a1-40e7-8d0a-39c8c04946fe

The open-access MAF lists 44 somatic variants for this specimen: 32 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 25, Silent 11, Nonsense Mutation 4, Frame Shift Ins 3, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARID1A | c.5161C>T p.R1721* | Nonsense Mutation (SNP) | VAF 107/214 reads (50%) | hotspot (GDC flag); catalogued as COSV61371260; called by muse, mutect2, varscan2
- BRD7 | c.1365T>G p.Y455* | Nonsense Mutation (SNP) | VAF 41/61 reads (67%) | hotspot (GDC flag); catalogued as COSV67158199, COSV67158513; called by muse, mutect2, varscan2
- ASAH2 | c.11G>A p.R4H | Missense Mutation (SNP) | VAF 35/98 reads (36%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as rs376205298; called by muse, mutect2, varscan2
- COL12A1 | c.1350C>A p.S450R | Missense Mutation (SNP) | VAF 54/86 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59392326; called by muse, mutect2, varscan2
- DCSTAMP | c.308C>A p.T103K | Missense Mutation (SNP) | VAF 82/204 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1255198244, COSV52576881; called by muse, mutect2, varscan2
- EIF4G2 | c.2141G>A p.R714H | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); catalogued as COSV60596538; called by muse, mutect2, varscan2
- EPN3 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.586); catalogued as rs146173668; called by muse, varscan2
- IL18RAP | c.1665G>T p.M555I | Missense Mutation (SNP) | VAF 58/140 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV51825073; called by muse, mutect2, varscan2
- INHBA | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 38/66 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV54220417; called by muse, varscan2
- IRF2 | c.571G>T p.E191* | Nonsense Mutation (SNP) | VAF 77/93 reads (83%) | catalogued as COSV66929027; called by muse, mutect2, varscan2
- LCE1B | c.118G>T p.V40F | Missense Mutation (SNP) | VAF 165/746 reads (22%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.648); catalogued as COSV63980188; called by muse, mutect2, varscan2
- MAPK4 | c.302C>T p.A101V | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs556250636, COSV68541439; called by muse, mutect2, varscan2
- NXF1 | c.1024C>G p.R342G | Missense Mutation (SNP) | VAF 42/87 reads (48%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); catalogued as COSV53672939, COSV53676395; called by muse, mutect2, varscan2
- OR2M3 | c.404T>C p.L135P | Missense Mutation (SNP) | VAF 180/834 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV71758949; called by muse, mutect2, varscan2
- PACS2 | c.2191G>A p.G731R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as rs782373206, COSV57651132; called by muse, mutect2, varscan2
- PLA2R1 | c.2417T>C p.I806T | Missense Mutation (SNP) | VAF 104/223 reads (47%) | SIFT tolerated (0.35); PolyPhen benign (0.116); catalogued as COSV51776614; called by muse, mutect2, varscan2
- PSMC5 | c.715C>T p.R239W | Missense Mutation (SNP) | VAF 32/108 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56738498; called by muse, mutect2, varscan2
- RPS6KA3 | c.76C>T p.Q26* | Nonsense Mutation (SNP) | VAF 186/222 reads (84%) | catalogued as COSV65432467; called by muse, mutect2, varscan2
- SI | c.2717C>T p.T906I | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.041); catalogued as COSV52271352; called by muse, mutect2, varscan2
- SLC26A4 | c.682G>T p.A228S | Missense Mutation (SNP) | VAF 24/310 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as CD073698, COSV55915288; called by muse, mutect2
- SPATA3 | c.428A>T p.Q143L | Missense Mutation (SNP) | VAF 47/117 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV69201680; called by muse, mutect2, varscan2
- SPTBN1 | c.3421C>T p.R1141W | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1371716918; called by muse, varscan2
- STON2 | c.1070C>T p.T357M (on ENST00000649389 / NM_001366849.2; = p.T300M on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.01); catalogued as rs201611443; called by muse, mutect2, varscan2
- TJP1 | c.2876C>T p.P959L | Missense Mutation (SNP) | VAF 112/249 reads (45%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.001); catalogued as COSV62040543; called by muse, mutect2, varscan2
- TOM1L1 | c.378G>C p.W126C | Missense Mutation (SNP) | VAF 63/132 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.479); catalogued as COSV61946955; called by muse, mutect2, varscan2
- TRPM6 | c.6044C>A p.S2015Y | Missense Mutation (SNP) | VAF 91/241 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as COSV62505810; called by muse, mutect2, varscan2
- VPS13A | c.2192G>A p.R731Q | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs746836759, COSV62426996; called by muse, mutect2, varscan2
- ZBTB1 | c.1478A>G p.N493S | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV62437673; called by muse, mutect2, varscan2
- ZDHHC22 | c.79C>T p.L27F | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV60057783; called by muse, mutect2, varscan2
- ARID1A | c.6504_6505insT p.V2169Cfs*56 | Frame Shift Ins (INS) | VAF 12/60 reads (20%) | called by mutect2, varscan2
- AXIN1 | c.1939dup p.R647Pfs*17 | Frame Shift Ins (INS) | VAF 38/50 reads (76%) | called by mutect2, varscan2
- HIVEP1 | c.5123dup p.N1708Kfs*38 | Frame Shift Ins (INS) | VAF 41/209 reads (20%) | called by mutect2, varscan2
- ARHGAP18 | c.1350C>T p.N450= | Silent (SNP) | VAF 60/81 reads (74%) | catalogued as COSV63763955, COSV63766296; called by muse, mutect2, varscan2
- FBN2 | c.3177T>A p.A1059= | Silent (SNP) | VAF 25/85 reads (29%) | catalogued as rs755961856, COSV52503145; called by muse, mutect2, varscan2
- ITGB3 | c.2352G>C p.T784= | Silent (SNP) | VAF 91/213 reads (43%) | catalogued as COSV101457558, COSV71383701; called by muse, mutect2, varscan2
- MYO7A | c.5661G>A p.P1887= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs375627342, COSV68684835; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- NCAPD3 | c.3792C>T p.V1264= | Silent (SNP) | VAF 55/110 reads (50%) | catalogued as COSV73187775; called by muse, mutect2, varscan2
- RBM27 | c.1956G>A p.R652= | Silent (SNP) | VAF 70/210 reads (33%) | catalogued as rs1235193211, COSV54588588; called by muse, mutect2, varscan2
- ROBO4 | c.1509G>T p.L503= | Silent (SNP) | VAF 100/261 reads (38%) | catalogued as COSV60622609, COSV60626494; called by muse, mutect2, varscan2
- RTL1 | c.2376C>T p.N792= | Silent (SNP) | VAF 62/143 reads (43%) | catalogued as rs1373326953, COSV66016590; called by muse, mutect2, varscan2
- TNS1 | c.2919G>A p.P973= | Silent (SNP) | VAF 17/34 reads (50%) | catalogued as rs545831386, COSV50695085; called by muse, mutect2, varscan2
- VCAN | c.4752C>T p.P1584= | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as COSV54101444; called by muse, mutect2, varscan2
- ZNF107 | c.882T>C p.H294= | Silent (SNP) | VAF 37/73 reads (51%) | catalogued as COSV61327539; called by muse, mutect2, varscan2
- OR4N3P | n.398C>G | RNA (SNP) | VAF 149/787 reads (19%) | called by muse, mutect2, varscan2
